Somatic mutation profile of tumor specimen TARGET-20-PARLFE-03A (aliquot TARGET-20-PARLFE-03A-01D) from TARGET case TARGET-20-PARLFE, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 17.4 years (6,353 days).
Specimen TARGET-20-PARLFE-03A: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b8fceb60-4fe6-4aea-b25f-655171c3378d.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PARLFE-14A (Bone Marrow Normal), aliquot TARGET-20-PARLFE-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d93f9516-766f-4df9-8c69-cf742d54b5f6

The open-access MAF lists 24 somatic variants for this specimen: 10 protein-altering or splice-affecting, 4 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Silent 4, 3'UTR 4, Intron 3, 3'Flank 2, 5'UTR 1, Frame Shift Ins 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.38G>T p.G13V | Missense Mutation (SNP) | VAF 48/268 reads (18%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.968); catalogued as rs121434596, CM071907, COSV54736416, COSV54736480, COSV54736793; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AXL | c.236C>T p.A79V | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.062); catalogued as rs776776986, COSV56569765; called by muse, mutect2, varscan2
- BCOR | c.3987G>C p.K1329N (on ENST00000378444 / NM_001123385.2; = p.K1295N on NM_017745.6) | Missense Mutation (SNP) | VAF 37/166 reads (22%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.996); catalogued as rs752258567; called by muse, mutect2, varscan2
- DGCR8 | c.1205C>T p.P402L | Missense Mutation (SNP) | VAF 33/180 reads (18%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs756087746; called by muse, mutect2, varscan2
- FAT2 | c.11335A>G p.S3779G | Missense Mutation (SNP) | VAF 54/254 reads (21%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs935128481; called by muse, mutect2, varscan2
- NPM1 | c.863_864insCATG p.W288Cfs*12 | Frame Shift Ins (INS) | VAF 8/66 reads (12%) | catalogued as rs1554138188, COSV51544217, COSV51551832, COSV51558469, COSV51558827, COSV51561854; called by pindel, varscan2
- PABPC3 | c.1270C>T p.R424* | Nonsense Mutation (SNP) | VAF 87/424 reads (21%) | catalogued as rs146343516; called by muse, mutect2, varscan2
- PPP6R3 | c.1793T>C p.I598T (on ENST00000393800 / NM_001352375.2; = p.I518T on NM_018312.5) | Missense Mutation (SNP) | VAF 36/202 reads (18%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs777906905; called by muse, mutect2, varscan2
- SMC3 | c.1982G>C p.R661P | Missense Mutation (SNP) | VAF 39/226 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV62421429, COSV62423179; called by muse, mutect2, varscan2
- TJP3 | c.2431G>A p.G811S | Missense Mutation (SNP) | VAF 37/149 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.312); catalogued as rs746465166, COSV53661405; called by muse, mutect2, varscan2
- MACF1 | c.16083A>G p.A5361= (on ENST00000372915; = p.A3294= on NM_012090.5) | Silent (SNP) | VAF 62/292 reads (21%) | catalogued as rs761117158; called by muse, mutect2, varscan2
- MACF1 | c.18525A>G p.E6175= (on ENST00000372915; = p.E4220= on NM_012090.5) | Silent (SNP) | VAF 86/322 reads (27%) | catalogued as rs754144854; called by muse, mutect2, varscan2
- RYR1 | c.255G>A p.V85= | Silent (SNP) | VAF 11/42 reads (26%) | catalogued as rs532101469; called by muse, varscan2
- TRRAP | c.219C>T p.L73= | Silent (SNP) | VAF 50/268 reads (19%) | catalogued as rs782732311; called by muse, mutect2, varscan2
- ARID1B | chr6:157210001 C>T | 3'Flank (SNP) | VAF 101/416 reads (24%) | called by muse, mutect2, varscan2
- DPH2 | c.*12G>C | 3'UTR (SNP) | VAF 31/221 reads (14%) | catalogued as rs753089088; called by muse, mutect2, varscan2
- KDR | c.-174C>A | 5'UTR (SNP) | VAF 19/87 reads (22%) | called by muse, mutect2, varscan2
- MAD1L1 | c.*49G>A | 3'UTR (SNP) | VAF 12/60 reads (20%) | catalogued as rs762109781; called by muse, mutect2, varscan2
- MLLT10 | c.405+49T>G | Intron (SNP) | VAF 23/139 reads (17%) | catalogued as rs766483233; called by muse, mutect2, varscan2
- PIGQ | c.1069+17C>T | Intron (SNP) | VAF 19/74 reads (26%) | catalogued as rs911815057; called by muse, mutect2, varscan2
- SIGLEC1 | c.*652C>T | 3'UTR (SNP) | VAF 44/184 reads (24%) | catalogued as rs939963927; called by muse, mutect2, varscan2
- SUPT5H | c.1037+42C>T | Intron (SNP) | VAF 22/122 reads (18%) | catalogued as rs780606543; called by muse, mutect2
- VANGL1 | chr1:115694877 G>T | 3'Flank (SNP) | VAF 71/342 reads (21%) | catalogued as rs1469462418; called by muse, mutect2, varscan2
- ZEB2 | c.*392C>T | 3'UTR (SNP) | VAF 73/269 reads (27%) | catalogued as rs190200609; called by muse, mutect2, varscan2
